Somatic mutation profile of tumor specimen C3L-09049-03 (aliquot CPT0499090010) from CPTAC case C3L-09049, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 67.8 years (24,760 days).
Specimen C3L-09049-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfa76cad-3bae-49f1-a806-ef46d89fb460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09049-31 (Blood Derived Normal), aliquot CPT0499220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ed6a0cc-3629-4ede-a7df-15673b4ec160

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, 5'Flank 1, 3'Flank 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 37/269 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA2D2 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs969458402, COSV56560321; called by muse, mutect2
- EIF2AK3 | c.3293C>T p.S1098L | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs770232594, COSV57546895; called by muse, mutect2
- FREM2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 28/493 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1470048580, COSV54837097; called by muse, mutect2
- GABRA5 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV59480384; called by muse, mutect2
- GJC2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 22/592 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs1482005574; called by muse, mutect2
- HTR2C | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs782783355, COSV52213889; called by muse, mutect2
- INTS1 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1266292328, COSV67178228; called by muse, mutect2
- KCNA10 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 18/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190117605; called by muse, mutect2
- KIF24 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61456189; called by muse, mutect2
- MMP11 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1020130023, COSV53157683; called by muse, mutect2
- NPR1 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs1348006342; called by muse, mutect2
- NPR3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1324958176; called by muse, mutect2
- PAPPA2 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs541683741, COSV62784683; called by muse, mutect2
- STXBP5L | c.2969G>A p.S990N | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56502418, COSV56539689; called by muse, mutect2
- TRIM7 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1385191219; called by muse, mutect2
- ASIC2 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- HOXD13 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- MN1 | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 21/626 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); called by muse, mutect2
- NOTCH2 | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2
- PLXNB3 | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 26/416 reads (6%) | called by muse, mutect2
- BTBD17 | c.729G>A p.P243= | Silent (SNP) | VAF 26/522 reads (5%) | called by muse, mutect2
- HCRTR1 | c.1107T>C p.F369= | Silent (SNP) | VAF 11/296 reads (4%) | called by muse, mutect2
- MYO1H | c.111G>A p.A37= | Silent (SNP) | VAF 20/376 reads (5%) | catalogued as rs548292658, COSV60451628; called by muse, mutect2
- TKTL1 | c.960T>C p.T320= | Silent (SNP) | VAF 17/534 reads (3%) | called by muse, mutect2
- AL353804.7 | chrX:73851932 A>G | 3'Flank (SNP) | VAF 14/367 reads (4%) | called by muse, mutect2
- MAGT1 | c.-4G>C | 5'UTR (SNP) | VAF 16/498 reads (3%) | called by muse, mutect2
- SH2B2 | chr7:102281870 C>T | 5'Flank (SNP) | VAF 18/334 reads (5%) | catalogued as rs372479780; called by muse, mutect2
